Somatic mutation profile of tumor specimen TCGA-AX-A3G9-01A (aliquot TCGA-AX-A3G9-01A-11D-A228-09) from TCGA case TCGA-AX-A3G9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.0 years (23,361 days).
Specimen TCGA-AX-A3G9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0f53419-3e1a-4c6c-958e-676c66992758.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3G9-10A (Blood Derived Normal), aliquot TCGA-AX-A3G9-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb29dd7e-8386-46c2-b554-c0cd9a1eb8cb

The open-access MAF lists 794 somatic variants for this specimen: 600 protein-altering or splice-affecting, 170 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 381, Silent 170, Frame Shift Del 145, Nonsense Mutation 28, Frame Shift Ins 18, In Frame Del 14, Intron 10, RNA 7, Splice Region 6, Splice Site 5, 3'Flank 4, Translation Start Site 2.

Variants (750 of 794; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137854532, CM930348, COSV55688292; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 20/48 reads (42%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHP1 | c.555del p.K185Nfs*7 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs766524637, CD1511891; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAX2 | c.76dup p.V26Gfs*28 | Frame Shift Ins (INS) | VAF 18/47 reads (38%) | catalogued as rs75462234; ClinVar: pathogenic; called by mutect2, varscan2
- PMS2 | c.1239dup p.D414Rfs*44 | Frame Shift Ins (INS) | VAF 27/72 reads (38%) | catalogued as rs267608159; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 39/46 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs369501242, COSV62932583; called by muse, mutect2, varscan2
- ABCA2 | c.6419del p.G2140Afs*11 (on ENST00000614293; = p.G2110Afs*11 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs1174224102; called by mutect2, pindel, varscan2
- ABCA7 | c.3658C>T p.Q1220* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99565565; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABCC3 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV99558985; called by muse, mutect2, varscan2
- ABI3BP | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as rs200430556; called by muse, mutect2, varscan2
- AC018755.2 | c.421+1G>A p.X141_splice | Splice Site (SNP) | VAF 43/67 reads (64%) | catalogued as rs1391171093, COSV99707394; called by muse, mutect2, varscan2
- AC139530.2 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100381698; called by muse, mutect2, varscan2
- ACACB | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV100622690; called by muse, mutect2, varscan2
- ACBD3 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs748746667, COSV100830966; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 27/65 reads (42%) | catalogued as rs757016425; called by mutect2, varscan2
- ACER2 | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100575788; called by muse, mutect2, varscan2
- ACTN1 | c.1439G>A p.C480Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.319); catalogued as COSV99517634; called by muse, mutect2, varscan2
- ACTN2 | c.1433A>G p.N478S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100856721; called by muse, mutect2, varscan2
- ADCY2 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV100602503; called by muse, varscan2
- ADCY5 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101518419; called by muse, mutect2, varscan2
- ADCY7 | c.1935G>A p.S645= | Splice Region (SNP) | VAF 33/79 reads (42%) | catalogued as rs556897150, COSV54268205; called by muse, mutect2, varscan2
- ADGRE1 | c.2153A>G p.Y718C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99165176; called by muse, mutect2, varscan2
- ADGRF2 | c.1822G>A p.V608M (on ENST00000296862 / NM_001368115.2; = p.V540M on NM_153839.7) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs994664007, COSV99731032; called by muse, mutect2, varscan2
- ADIPOR2 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs767407914, COSV100840072; called by muse, mutect2, varscan2
- AGTR1 | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100836999; called by muse, mutect2, varscan2
- AK9 | c.3407T>G p.L1136W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100393511; called by muse, mutect2, varscan2
- AKAP11 | c.3829G>A p.V1277I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV99213757; called by muse, mutect2, varscan2
- ALAD | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs144531057; called by muse, mutect2, varscan2
- ALMS1 | c.938del p.L313Yfs*18 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs771675011; called by mutect2, pindel, varscan2
- ALPK2 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs199755126; called by muse, mutect2, varscan2
- ANAPC1 | c.5029C>T p.L1677F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV100594637; called by mutect2, varscan2
- ANXA2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as rs767606956, COSV100221950; called by muse, mutect2, varscan2
- AP4B1 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56723403, COSV99870710; called by muse, mutect2, varscan2
- APCDD1L | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482097793, COSV100953972; called by muse, mutect2
- ARAP1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1393767675, COSV61994758; called by muse, mutect2, varscan2
- ARAP3 | c.4393C>T p.P1465S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as COSV53351295; called by muse, mutect2, varscan2
- ARHGAP27 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51818143; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARL10 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100119028; called by muse, mutect2, varscan2
- ARSH | c.1271T>C p.F424S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101139801; called by muse, mutect2, varscan2
- ASMTL | c.1117C>A p.L373M | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101187736; called by muse, mutect2, varscan2
- ATM | c.4925G>T p.G1642V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99589046; called by muse, mutect2, varscan2
- ATM | c.5986_5988del p.E1996del | In Frame Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs1555111872; called by pindel, varscan2
- ATP6V1C2 | c.1150G>A p.V384I (on ENST00000272238 / NM_001039362.2; = p.V338I on NM_144583.4) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55349669; called by muse, mutect2, varscan2
- AUTS2 | c.2531G>T p.R844M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100716106; called by muse, mutect2, varscan2
- AVPR2 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100509477; called by muse, mutect2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BAHD1 | c.37A>T p.S13C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV101346747; called by muse, mutect2, varscan2
- BCKDK | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV99570569; called by muse, mutect2, varscan2
- BDH1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV100827100; called by muse, varscan2
- BMP15 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as COSV99399332; called by muse, mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BOLA1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs371656521; called by muse, mutect2, varscan2
- BRD1 | c.1091T>A p.M364K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99349576; called by muse, mutect2, varscan2
- BRWD3 | c.5180G>A p.R1727H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.382); catalogued as rs144015236, COSV100955915; called by muse, mutect2, varscan2
- C10orf82 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV100980085, COSV65024767; called by muse, mutect2
- C1QTNF4 | c.812G>T p.S271I | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100209252; called by muse, mutect2, varscan2
- C1orf56 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99764605; called by muse, mutect2, varscan2
- C1orf56 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs778359132, COSV99764606; called by muse, mutect2, varscan2
- C2CD6 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs761105294, COSV99632520; called by muse, mutect2, varscan2
- CADPS2 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100460571; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN9 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200358258, COSV55235150; called by muse, mutect2, varscan2
- CARD14 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as rs777053396, COSV100712536; called by muse, mutect2, varscan2
- CARMIL1 | c.3009C>A p.V1003= | Splice Region (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100277458, COSV61514000; called by muse, mutect2, varscan2
- CASP5 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99507450; called by mutect2, varscan2
- CASP8AP2 | c.4543C>T p.R1515* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99386954; called by muse, mutect2, varscan2
- CBR3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1317275693, COSV99289772; called by muse, mutect2, varscan2
- CCDC120 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs781929013, COSV100900613; called by muse, mutect2, varscan2
- CCDC124 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101506488; called by muse, mutect2, varscan2
- CCDC144A | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs777407520, COSV60697225, COSV60699146; called by muse, mutect2, varscan2
- CCDC88C | c.1349G>T p.R450M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101105494; called by muse, mutect2, varscan2
- CCNG1 | c.142A>C p.T48P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100546720; called by muse, mutect2, varscan2
- CCNI | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.316); catalogued as COSV99423329; called by muse, mutect2, varscan2
- CCR8 | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100413064; called by muse, mutect2, varscan2
- CCS | c.285del p.P96Lfs*13 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs759691599; called by mutect2, pindel, varscan2
- CCSER1 | c.1771T>C p.C591R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV100389972; called by muse, mutect2
- CCT8L2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.407); catalogued as rs755816031, COSV100742661; called by muse, mutect2, varscan2
- CD244 | c.578G>A p.G193D (on ENST00000368033 / NM_001166663.2; = p.G188D on NM_016382.4) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1476759172, COSV100458406; called by muse, mutect2, varscan2
- CD5L | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs772726189, COSV100941030; called by muse, mutect2, varscan2
- CDC42BPG | c.1074del p.M360Wfs*70 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as COSV61347497; called by mutect2, pindel, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | catalogued as rs762194001; called by mutect2, varscan2
- CDHR2 | c.458T>C p.M153T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266041496, COSV99991396; called by muse, mutect2, varscan2
- CDK20 | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100308040; called by muse, mutect2
- CELSR1 | c.7872C>T p.I2624= | Splice Region (SNP) | VAF 34/83 reads (41%) | catalogued as rs769638723, COSV53084031; called by muse, mutect2, varscan2
- CENPB | c.1312del p.E438Kfs*43 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | catalogued as rs748211874; called by mutect2, pindel, varscan2
- CES4A | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 41/92 reads (45%) | catalogued as rs1286888773, COSV100110039; called by muse, mutect2, varscan2
- CFHR4 | c.1728C>A p.C576* (on ENST00000367416 / NM_001201551.2; = p.C330* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs760031130, COSV52228799, COSV99260098; called by muse, mutect2, varscan2
- CHD3 | c.5914_5916del p.K1972del (on ENST00000330494 / NM_001005273.3; = p.K1938del on NM_005852.4) | In Frame Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs768305286; called by pindel, varscan2
- CHD6 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58562686; called by muse, mutect2, varscan2
- CHD9 | c.6856A>C p.S2286R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.617); catalogued as COSV99529033; called by muse, mutect2, varscan2
- CHEK2 | c.668G>A p.R223H (on ENST00000382580 / NM_001005735.2; = p.R180H on NM_007194.4) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs137853009, CM030418, COSV60417374; ClinVar: conflicting interpretations of pathogenicity / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CHERP | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1279094830, COSV99550163; called by muse, mutect2
- CHML | c.1673A>G p.D558G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100087251; called by muse, mutect2, varscan2
- CHPF2 | c.1941del p.S648Pfs*13 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs746469175; called by mutect2, varscan2
- CHST5 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60341692; called by muse, mutect2, varscan2
- CHST5 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100291875; called by muse, mutect2, varscan2
- CHUK | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100957061; called by muse, mutect2, varscan2
- CIT | c.5389C>T p.R1797* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1391231312, COSV99949189; called by muse, mutect2, varscan2
- CITED2 | c.374A>T p.N125I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV100863104; called by muse, mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs749719822, COSV99752279; called by mutect2, pindel, varscan2
- CLCN2 | c.592A>G p.S198G | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1214048963, COSV99658442; called by muse, mutect2, varscan2
- CLSTN2 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71721149; called by muse, mutect2, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/75 reads (43%) | catalogued as rs752224729; called by mutect2, pindel, varscan2
- CNTN4 | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100639144; called by muse, mutect2, varscan2
- CNTNAP5 | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs201213643, COSV70490115; called by muse, mutect2, varscan2
- COL17A1 | c.2524G>T p.G842C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793122; called by muse, mutect2, varscan2
- COL18A1 | c.4289del p.P1430Lfs*16 (on ENST00000359759 / NM_130444.3; = p.P1195Lfs*16 on NM_030582.4) | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs748210520; called by mutect2, pindel, varscan2
- COL25A1 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV101211318; called by muse, mutect2, varscan2
- COL4A2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201457127, COSV100847306; called by muse, mutect2, varscan2
- COPB2 | c.2651T>C p.L884S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV100169034; called by muse, mutect2, varscan2
- COPG1 | c.322A>G p.S108G | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100135515; called by muse, mutect2
- CP | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs765169503, COSV99223978; called by muse, mutect2, varscan2
- CPN2 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100103015; called by muse, mutect2, varscan2
- CPSF6 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99879183; called by muse, mutect2, varscan2
- CTBP1 | c.1280T>G p.V427G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52072013, COSV99337679; called by muse, mutect2, varscan2
- CTNND1 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100649989; called by muse, mutect2, varscan2
- CTNND1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.913); catalogued as rs770665127, COSV62382269; called by muse, mutect2, varscan2
- CUL5 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV101263657; called by muse, mutect2, varscan2
- CYLD | c.2296T>C p.F766L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV100282361; called by muse, mutect2, varscan2
- CYP21A2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371412889, CM130870; called by muse, mutect2, varscan2
- DAB2IP | c.2185T>C p.Y729H (on ENST00000408936; = p.Y701H on NM_032552.3) | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV99405182; called by muse, mutect2, varscan2
- DAPK1 | c.3944G>A p.R1315H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as rs368364961; called by muse, mutect2, varscan2
- DCDC2B | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100557180; called by muse, mutect2, varscan2
- DDX25 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs75377442, COSV99699830; called by muse, mutect2, varscan2
- DDX51 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs753901298, COSV57959934; called by mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs553532837; called by mutect2, varscan2
- DGCR2 | c.1216T>G p.F406V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV99593532; called by muse, mutect2, varscan2
- DHX30 | c.463C>T p.R155C (on ENST00000445061 / NM_138615.3; = p.R116C on NM_014966.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.454); catalogued as rs769809768, COSV62394225; called by muse, mutect2, varscan2
- DHX34 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs768588954, COSV100169449; called by muse, varscan2
- DIPK2B | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474836507, COSV67641306; called by muse, mutect2, varscan2
- DIRAS1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60215858; called by muse, mutect2, varscan2
- DIS3L2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as rs377321022; called by muse, mutect2, varscan2
- DLC1 | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99362415; called by muse, mutect2, varscan2
- DLGAP2 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs777261867, COSV101421623; called by muse, mutect2, varscan2
- DNAH10 | c.10907G>A p.R3636Q (on ENST00000409039; = p.R3575Q on NM_207437.3) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762248686, COSV101292162; called by muse, mutect2, varscan2
- DNAH10 | c.12557G>A p.R4186Q (on ENST00000409039; = p.R4125Q on NM_207437.3) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs779810590, COSV68989568; called by muse, mutect2, varscan2
- DNAH5 | c.12104C>T p.T4035M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs200894344, COSV54232968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.7474G>A p.A2492T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54202086, COSV54222629, COSV54234650; called by muse, mutect2
- DNAH7 | c.4853C>T p.A1618V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.721); catalogued as rs1025144874, COSV100414697; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH9 | c.3496T>G p.F1166V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99305242; called by muse, mutect2, varscan2
- DNAH9 | c.7853C>T p.P2618L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756305371, COSV52366132, COSV52369207; called by muse, mutect2, varscan2
- DOCK1 | c.1970C>G p.A657G | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99728639; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPP9 | c.1720G>A p.V574I (on ENST00000598800; = p.V603I on NM_139159.5) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs369918302; called by muse, varscan2
- DPYSL2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs765937076, COSV60784077; called by muse, mutect2, varscan2
- DUSP26 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); catalogued as rs777238685, COSV99823389; called by muse, mutect2, varscan2
- DYNC2H1 | c.6146G>A p.S2049N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100518184; called by muse, mutect2, varscan2
- E2F3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138776759; called by muse, mutect2, varscan2
- E4F1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs776338481, COSV100065575; called by muse, mutect2, varscan2
- EIF2B1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99967535; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs748937918; called by mutect2, varscan2
- EMID1 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as rs762477700, COSV99328491; called by muse, mutect2, varscan2
- ENPP5 | c.1053A>G p.I351M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100040414; called by muse, mutect2, varscan2
- EPHA8 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs775244487, COSV99384609; called by muse, mutect2, varscan2
- ERG | c.1066C>T p.R356W (on ENST00000398919 / NM_001243428.1; = p.R332W on NM_004449.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750603713, COSV55731477; called by muse, mutect2, varscan2
- ESRRG | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV100752661; called by muse, mutect2, varscan2
- EVPL | c.5600dup p.I1868Hfs*8 | Frame Shift Ins (INS) | VAF 29/90 reads (32%) | catalogued as rs1567905335; called by mutect2, pindel, varscan2
- FAM114A2 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs781759624, COSV100697636; called by muse, mutect2, varscan2
- FAM120A | c.1334C>A p.P445H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99465091; called by muse, mutect2, varscan2
- FAM135B | c.4063G>T p.E1355* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99422191; called by muse, mutect2, varscan2
- FAM155B | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99368284; called by muse, mutect2, varscan2
- FAM222B | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs762089934, COSV100368412; called by muse, mutect2, varscan2
- FASTKD2 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV99378905; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs773607911, COSV52947201; called by mutect2, pindel, varscan2
- FBN2 | c.4135G>A p.D1379N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs770322643, COSV52507347, COSV99326502; called by muse, mutect2, varscan2
- FBN2 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761958762, COSV52494404; called by muse, mutect2, varscan2
- FBXO16 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774774236, COSV100672243; called by muse, mutect2, varscan2
- FGD5 | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53248535, COSV99547811; called by muse, mutect2, varscan2
- FGD6 | c.3188A>G p.Q1063R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100676504; called by muse, mutect2
- FHL2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs750377257, COSV59079369; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs777980924; called by mutect2, varscan2
- FNDC5 | c.618del p.L207Ffs*69 | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | catalogued as COSV65106005; called by mutect2, pindel, varscan2
- FRMPD1 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746113446, COSV66700067; called by muse, mutect2, varscan2
- GABPA | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV61395627; called by muse, mutect2, varscan2
- GAREM1 | c.2540C>T p.T847M (on ENST00000269209 / NM_001242409.2; = p.T846M on NM_022751.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs773814148, COSV99330470; called by muse, mutect2, varscan2
- GCSAML | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.873); catalogued as COSV63578235; called by muse, mutect2, varscan2
- GDF5 | c.498del p.I167Sfs*26 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as CD016280; called by mutect2, pindel, varscan2
- GLCCI1 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV99780287; called by muse, mutect2, varscan2
- GLG1 | c.1339del p.E447Rfs*19 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs1567477383; called by mutect2, pindel, varscan2
- GLI2 | c.1532C>T p.T511I (on ENST00000361492 / NM_001374353.1; = p.T528I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100082879; called by muse, mutect2, varscan2
- GLUL | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV59383488; called by muse, mutect2, varscan2
- GMPS | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV55808670; called by muse, mutect2, varscan2
- GPSM1 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as rs1344010699, COSV100696583; called by muse, mutect2
- GREB1 | c.3914C>A p.S1305Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV52195722, COSV99302717; called by muse, mutect2, varscan2
- GRIN2A | c.1097T>C p.L366P | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100409324; called by muse, mutect2, varscan2
- GRM3 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs776686228, COSV100862421; called by muse, mutect2, varscan2
- GRM6 | c.2368T>C p.Y790H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179544; called by muse, mutect2, varscan2
- GTF2H1 | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV56379786; called by muse, mutect2, varscan2
- GTF3C1 | c.5077G>A p.A1693T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs749257962, COSV100649257; called by muse, mutect2, varscan2
- GTF3C5 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs143172359, COSV59598934; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel, varscan2
- HAP1 | c.1091C>A p.A364D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100169600; called by muse, mutect2, varscan2
- HAPLN4 | c.705del p.T236Pfs*43 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as COSV52270379; called by mutect2, pindel, varscan2
- HAUS5 | c.833C>A p.P278Q | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.52); PolyPhen benign (0.082); catalogued as COSV52549988, COSV99178292; called by muse, mutect2, varscan2
- HDAC5 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs750672810, COSV99870516; called by muse, mutect2, varscan2
- HECW1 | c.4253C>T p.T1418M | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs746516271, COSV67843394; called by muse, mutect2, varscan2
- HERC2 | c.6661G>A p.G2221S | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs781114289, COSV99872597; called by muse, mutect2, varscan2
- HEXB | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs769208361, COSV99714220; called by muse, mutect2
- HGS | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV100230395; called by muse, mutect2, varscan2
- HIC2 | c.1842del p.S615Pfs*25 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as COSV101335588; called by mutect2, pindel, varscan2
- HPCAL4 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100864766; called by muse, mutect2, varscan2
- HRNR | c.5149C>T p.R1717* | Nonsense Mutation (SNP) | VAF 22/355 reads (6%) | catalogued as rs1263607205; called by muse, mutect2
- HTR2C | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.743); catalogued as COSV52215800, COSV99348841; called by muse, varscan2
- HYDIN | c.5674C>T p.R1892C | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198665807, COSV99992517; called by muse, mutect2, varscan2
- IBTK | c.2474A>G p.D825G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100090516; called by muse, mutect2, varscan2
- IER5L | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV100993597; called by muse, mutect2, varscan2
- IFIT1B | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100879068; called by muse, mutect2, varscan2
- IFT46 | c.713A>C p.E238A (on ENST00000264021 / NM_001168618.2; = p.E289A on NM_020153.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV99870970; called by muse, mutect2, varscan2
- IGDCC4 | c.2613del p.T872Qfs*11 | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | catalogued as COSV61539288; called by mutect2, pindel, varscan2
- IGF1R | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs369599027, COSV51297346; called by muse, mutect2, varscan2
- IGF2 | c.686del p.P229Qfs*27 (on ENST00000434045 / NM_001127598.3; = p.P173Qfs*27 on NM_000612.6) | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as rs755455183; ClinVar: uncertain significance; called by mutect2, pindel
- IGF2BP1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs1364176184, COSV51731262; called by muse, mutect2, varscan2
- IL17RD | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99576908; called by muse, mutect2
- INPP1 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100487166; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs760925109; called by mutect2, pindel
- INPPL1 | c.3739A>T p.K1247* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as COSV99996104; called by muse, mutect2, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | catalogued as rs779930616; called by mutect2, pindel, varscan2
- INTS13 | c.1489dup p.T497Nfs*7 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | catalogued as rs1363242314; called by pindel, varscan2
- INVS | c.1709A>C p.K570T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV99317368; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQCE | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV58080875; called by muse, mutect2, varscan2
- IRF2BP2 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as COSV64015366; called by muse, mutect2, varscan2
- ITGAV | c.3007G>A p.A1003T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as COSV99654678; called by muse, mutect2, varscan2
- JAK1 | c.2210T>C p.L737P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100691488; called by muse, mutect2, varscan2
- JPH1 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100646529; called by muse, mutect2, varscan2
- KAZN | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs569722853, COSV100747755; called by muse, mutect2, varscan2
- KCNA3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1321970152, COSV100871235; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNJ14 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100655759; called by muse, mutect2, varscan2
- KCNK15 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV100865103; called by muse, mutect2, varscan2
- KIAA0100 | c.3205G>T p.G1069C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101197273; called by muse, mutect2, varscan2
- KIAA1549L | c.2180C>T p.A727V (on ENST00000321505; = p.A1024V on NM_012194.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.138); catalogued as COSV55772077; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 22/38 reads (58%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLK2 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as rs764309655, COSV100319906; called by muse, mutect2, varscan2
- KMT2D | c.3935G>A p.R1312H | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762289838, COSV56469192; called by muse, mutect2, varscan2
- KNL1 | c.5377G>C p.E1793Q (on ENST00000346991 / NM_170589.5; = p.E1767Q on NM_144508.5) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1170663121, COSV61153654; called by muse, mutect2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 68/166 reads (41%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KPNA5 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100706159; called by muse, mutect2, varscan2
- KRT14 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.293); catalogued as COSV99390964; called by muse, mutect2
- KRT20 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1192320676, COSV51424303; called by muse, mutect2, varscan2
- KRT9 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.087); catalogued as rs143561490; called by muse, mutect2, varscan2
- KRTAP2-1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs1238572660, COSV101195354; called by muse, mutect2, varscan2
- LAMTOR4 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100385439; called by muse, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LATS1 | c.2840A>G p.Q947R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs866088623, COSV99485692; called by muse, mutect2, varscan2
- LETM2 | c.1200_1201del p.E400Dfs*11 (on ENST00000379957 / NM_001286819.2; = p.E305Dfs*11 on NM_144652.3) | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs763212040; called by pindel, varscan2
- LILRB4 | c.1010C>T p.T337I (on ENST00000391733 / NM_001278428.3; = p.T336I on NM_001278426.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV99553698; called by muse, mutect2, varscan2
- LLPH | c.146C>G p.T49S | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV99874508; called by muse, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 8/20 reads (40%) | catalogued as rs765287063; called by mutect2, varscan2
- LPGAT1 | c.657A>T p.K219N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100878102; called by muse, mutect2, varscan2
- LRRC14 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.91); catalogued as rs1372269515, COSV99467422; called by muse, mutect2, varscan2
- LRRC37A3 | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs752877809, COSV58536385; called by muse, mutect2, varscan2
- LSS | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs549479604, COSV100710869; called by muse, mutect2, varscan2
- LYPD6B | c.382C>T p.H128Y (on ENST00000409029 / NM_001317004.1; = p.H152Y on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.835); catalogued as COSV99700145; called by muse, mutect2, varscan2
- MACF1 | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100483779; called by muse, mutect2, varscan2
- MADD | c.4113G>T p.L1371F | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100211314; called by muse, mutect2, varscan2
- MAGEA11 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV60753438, COSV60757013, COSV60758441; called by muse, mutect2, varscan2
- MAGI2 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762159792, COSV62638508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAMDC4 | c.3009del p.S1004Lfs*66 (on ENST00000445819; = p.S925Lfs*66 on NM_206920.3) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs775859928; called by pindel, varscan2
- MAPK8IP3 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs747795881, COSV99167841; called by muse, mutect2, varscan2
- MARF1 | c.3497G>A p.R1166H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750466646, COSV100705753; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs558765093; called by mutect2, varscan2
- MBTPS1 | c.2768C>A p.P923H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs775034108, COSV100597489; called by muse, mutect2, varscan2
- MDFI | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100025603; called by muse, mutect2
- MED12 | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV61359729; called by muse, mutect2, varscan2
- MED23 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.39); catalogued as COSV100644882; called by muse, mutect2, varscan2
- MFSD2A | c.117_119del p.Q40del | In Frame Del (DEL) | VAF 34/78 reads (44%) | catalogued as rs759313809; called by pindel, varscan2
- MGAT5B | c.1660C>T p.Q554* (on ENST00000569840 / NM_001199172.2; = p.Q552* on NM_144677.3) | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100047741; called by muse, mutect2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV55498546; called by mutect2, pindel, varscan2
- MIA2 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs754149612, COSV54482945; called by muse, mutect2, varscan2
- MICAL1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99237908; called by muse, mutect2, varscan2
- MIOX | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773855400, COSV99326809; called by muse, mutect2, varscan2
- MORN5 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs766633182, COSV65649312; called by muse, mutect2, varscan2
- MOSPD1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV100887826; called by muse, mutect2, varscan2
- MPND | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as rs1022934258, COSV99515117; called by muse, mutect2, varscan2
- MRC2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs751226940, COSV100315619, COSV57643725; called by muse, mutect2, varscan2
- MRPL34 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); catalogued as COSV53113065, COSV99395469; called by muse, mutect2, varscan2
- MTR | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150058137, CM159492; called by muse, mutect2, varscan2
- MTUS1 | c.1650_1653del p.T551Sfs*2 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs768393434; called by pindel, varscan2
- MUC5AC | c.15224G>A p.R5075H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs891593509; called by muse, mutect2
- MUC5B | c.14021G>A p.S4674N | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs757777263, COSV101500233; called by muse, mutect2, varscan2
- MUC5B | c.16450G>A p.V5484M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs752188250, COSV101500234; called by muse, mutect2, varscan2
- MYC | c.179C>T p.P60L (on ENST00000377970; = p.P75L on NM_002467.6) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367558, COSV52380145; called by muse, mutect2, varscan2
- MYH7 | c.4757C>T p.A1586V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV100805953; called by muse, mutect2, varscan2
- MYO18B | c.7615G>A p.E2539K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs978117915, COSV59129189, COSV59130140; called by muse, mutect2, varscan2
- MYO19 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs750807521; called by muse, mutect2, varscan2
- MYO7A | c.2920C>T p.R974W | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs782582076, COSV68683616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYORG | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99898490; called by muse, mutect2, varscan2
- NAV2 | c.7372G>A p.A2458T (on ENST00000396087 / NM_001244963.2; = p.A2399T on NM_145117.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1461466330, COSV60661546; called by muse, mutect2, varscan2
- NBPF11 | c.2006G>A p.G669D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as COSV100982129; called by muse, mutect2, varscan2
- NCBP1 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV64317221; called by muse, mutect2, varscan2
- NDUFA9 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs201327321, COSV99865482; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs747914168; called by mutect2, varscan2
- NECTIN1 | c.1219del p.Q407Sfs*191 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | catalogued as COSV50605488; called by mutect2, pindel, varscan2
- NEUROG3 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV99653478; called by muse, mutect2, varscan2
- NFAT5 | c.2786C>A p.S929* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100590677; called by muse, mutect2, varscan2
- NMT1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV51959564; called by muse, mutect2, varscan2
- NOMO3 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs746920059, COSV99530529; called by muse, mutect2, varscan2
- NOTCH1 | c.4665G>T p.E1555D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as COSV99486882; called by muse, mutect2
- NOVA1 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1325464323, COSV99947167; called by muse, mutect2, varscan2
- NOX4 | c.1581A>T p.K527N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV99630198; called by muse, mutect2, varscan2
- NOXRED1 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV99375528; called by muse, mutect2, varscan2
- NPAT | c.3292C>A p.L1098I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as COSV99585925; called by muse, mutect2, varscan2
- NPAT | c.945A>G p.I315M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99585926; called by mutect2, varscan2
- NPHP1 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM139023, COSV100337965; called by muse, mutect2, varscan2
- NSUN6 | c.1377del p.F459Lfs*6 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs768858112, COSV56613929; called by mutect2, pindel, varscan2
- NUDT12 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100048117; called by muse, mutect2, varscan2
- NUGGC | c.1403T>A p.L468Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100429152; called by muse, mutect2, varscan2
- NUP188 | c.4142C>T p.P1381L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs896425897, COSV100999702; called by muse, mutect2, varscan2
- NUSAP1 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370147837; called by muse, mutect2, varscan2
- NUTM2F | c.1175del p.P392Lfs*43 | Frame Shift Del (DEL) | VAF 84/207 reads (41%) | catalogued as rs771183172; called by mutect2, varscan2
- OAT | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as rs763064048, COSV100920411; called by muse, mutect2, varscan2
- OBI1 | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs747936802, COSV99932409; called by muse, mutect2, varscan2
- OGFOD2 | c.803T>C p.L268P (on ENST00000228922 / NM_001304833.1; = p.L208P on NM_024623.3) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.558); catalogued as COSV99758676; called by muse, mutect2, varscan2
- OR13C4 | c.647del p.F216Sfs*30 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs752116520, COSV52927828; called by mutect2, pindel, varscan2
- OR5AK2 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100475990; called by muse, mutect2, varscan2
- PARP4 | c.1208A>C p.H403P | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV101131480; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBLD | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs779129965, COSV99516067; called by muse, mutect2, varscan2
- PCDHA5 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as rs782086860, COSV100972218, COSV100972594; called by muse, mutect2, varscan2
- PCDHA5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.334); catalogued as COSV65349753; called by muse, mutect2, varscan2
- PCDHA9 | c.2126G>A p.S709N | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV65330571, COSV65331419; called by muse, mutect2, varscan2
- PCDHB11 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs1341901695, COSV61310069; called by muse, mutect2, varscan2
- PCDHB12 | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV53401960; called by muse, mutect2, varscan2
- PCDHB14 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.167); catalogued as COSV53386399, COSV53389436, COSV53391402; called by muse, mutect2
- PCDHGB2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1306730531, COSV54025302; called by muse, mutect2, varscan2
- PCDHGB3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53921139; called by muse, mutect2, varscan2
- PCED1A | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as COSV100642854; called by muse, mutect2, varscan2
- PCLO | c.2779G>A p.V927M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs765996457, COSV61642025, COSV61650906; called by muse, mutect2, varscan2
- PCNX1 | c.3347T>C p.L1116S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99455157; called by mutect2, varscan2
- PDE4B | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778940030, COSV58489182; called by muse, mutect2, varscan2
- PDIA3 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100295016, COSV55855215; called by muse, mutect2, varscan2
- PFKL | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778843887, COSV62462856; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PGBD5 | c.931A>G p.M311V (on ENST00000525115; = p.M380V on NM_001258311.2) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.203); catalogued as COSV100358500; called by muse, mutect2, varscan2
- PGM2L1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99994772; called by muse, mutect2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 16/24 reads (67%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHC2 | c.2329C>T p.R777W (on ENST00000257118 / NM_198040.2; = p.R242W on NM_004427.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs199838218, COSV99930615; called by muse, mutect2, varscan2
- PHEX | c.1574T>C p.V525A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV101039550; called by muse, mutect2, varscan2
- PIK3CD | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV63127533; called by muse, mutect2, varscan2
- PLA2G6 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100140328; called by muse, mutect2, varscan2
- PLAC8L1 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as rs1260248417, COSV100268725; called by muse, mutect2, varscan2
- PLAG1 | c.1373del p.P458Hfs*13 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as COSV57610471; called by mutect2, pindel, varscan2
- PLCH2 | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99616029; called by muse, mutect2, varscan2
- PLEC | c.11690G>A p.R3897H (on ENST00000322810 / NM_201380.4; = p.R3787H on NM_000445.5) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1554675610, COSV59705146; called by muse, mutect2, varscan2
- PLEKHA4 | c.1623del p.R542Gfs*14 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | catalogued as COSV99613268; called by mutect2, pindel, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs746342377, COSV56183473; called by mutect2, pindel, varscan2
- PLXNA4 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376529616; called by muse, mutect2, varscan2
- PLXNB2 | c.1817C>T p.T606M | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs751022390, COSV100833991; called by muse, mutect2, varscan2
- POM121 | c.850C>T p.R284C (on ENST00000434423; = p.R19C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs782555375, COSV99988025; called by muse, mutect2, varscan2
- POT1 | c.869del p.K290Rfs*3 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as COSV100713969; called by mutect2, pindel, varscan2
- PPP4R4 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100175658; called by muse, mutect2, varscan2
- PRAG1 | c.4100C>T p.A1367V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs748860973, COSV58162486; called by muse, mutect2, varscan2
- PREB | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs770885905, COSV53206698; called by muse, mutect2, varscan2
- PREX2 | c.2789G>T p.S930I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV99906407; called by muse, mutect2, varscan2
- PRPF6 | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs761298881, COSV53874810; called by muse, mutect2, varscan2
- PSD | c.2625del p.F876Sfs*36 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs1474910891, COSV99193631; called by mutect2, pindel, varscan2
- PSTK | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV100924783; called by muse, mutect2, varscan2
- PTCH1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59486895; called by muse, mutect2, varscan2
- PTPN21 | c.1824_1826del p.E608del | In Frame Del (DEL) | VAF 48/116 reads (41%) | catalogued as rs751049545; called by pindel, varscan2
- PTPRT | c.3283A>G p.I1095V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs777602624, COSV61993182; called by muse, mutect2, varscan2
- QRICH2 | c.4931G>A p.G1644D | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV53158229; called by muse, mutect2, varscan2
- RAB4B | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770414180, COSV100826431, COSV63825153; called by muse, mutect2, varscan2
- RAD1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as rs918087089, COSV100337569; called by muse, mutect2, varscan2
- RAD50 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765290694, COSV54757008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGAPB | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99485048; called by muse, mutect2, varscan2
- RDH13 | c.791C>A p.P264H (on ENST00000415061 / NM_001145971.2; = p.P193H on NM_138412.4) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99401437; called by muse, mutect2, varscan2
- RFX2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100353678; called by muse, mutect2, varscan2
- RFX6 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100263593; called by muse, mutect2, varscan2
- RIOX2 | c.1022del p.P341Lfs*23 (on ENST00000333396 / NM_001042533.2; = p.P340Lfs*23 on NM_032778.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/57 reads (46%) | catalogued as COSV51714857; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RPL19 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV56635148, COSV99841436; called by muse, mutect2, varscan2
- RPLP1 | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99532211; called by muse, mutect2, varscan2
- RPS6 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1177388889, COSV59548306; called by muse, mutect2, varscan2
- RSPO4 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369687640; called by muse, mutect2, varscan2
- RTF1 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs747435783, COSV67478060; called by muse, mutect2, varscan2
- RTL3 | c.985A>G p.I329V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs376204247, COSV100329677; called by mutect2, varscan2
- RUNDC3B | c.375T>A p.C125* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99712673; called by muse, mutect2, varscan2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs749201569; called by mutect2, varscan2
- SALL3 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as rs1424879091, COSV73305867; called by muse, mutect2
- SBF1 | c.2534G>A p.S845N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100817649; called by muse, mutect2, varscan2
- SCEL | c.290+1G>A p.X97_splice | Splice Site (SNP) | VAF 6/9 reads (67%) | catalogued as COSV100582806; called by muse, mutect2
- SEPTIN7 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100621749; called by muse, mutect2
- SETD1A | c.3126_3128del p.S1058del | In Frame Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs768655377; called by mutect2, pindel, varscan2
- SETDB1 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as rs147846533; called by muse, mutect2, varscan2
- SF3A1 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.981); catalogued as COSV99305370; called by muse, mutect2, varscan2
- SFI1 | c.2713C>G p.Q905E (on ENST00000400288 / NM_001007467.3; = p.Q874E on NM_014775.4) | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); catalogued as COSV100770141, COSV63475852; called by muse, mutect2, varscan2
- SFT2D1 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100674926; called by muse, mutect2, varscan2
- SH2B1 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs759368706, COSV59461527, COSV59463992; called by muse, mutect2, varscan2
- SH3TC2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs532463685, COSV60468004; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHOX2 | c.938C>A p.S313Y (on ENST00000441443 / NM_006884.3; = p.S337Y on NM_003030.4) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101273767; called by muse, varscan2
- SHOX2 | c.880G>A p.A294T (on ENST00000441443 / NM_006884.3; = p.A318T on NM_003030.4) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV101273768; called by muse, varscan2
- SI | c.1694G>T p.S565I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100014994; called by muse, mutect2, varscan2
- SIGLEC14 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs758347134, COSV55778609; called by muse, mutect2, varscan2
- SIRPA | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as rs776144552, COSV61541742; called by muse, varscan2
- SLC20A2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as CM1410693, COSV100646040; called by muse, mutect2, varscan2
- SLC22A11 | c.1309G>T p.G437* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57255716; called by muse, mutect2, varscan2
- SLC22A23 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1352167479, COSV100978186; called by muse, mutect2, varscan2
- SLC27A1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.227); catalogued as rs754160792, COSV53097133; called by muse, mutect2, varscan2
- SLC29A2 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs752771041, COSV100237067; called by muse, mutect2, varscan2
- SLC29A2 | c.136del p.A46Pfs*9 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV100237068; called by mutect2, pindel, varscan2
- SLC30A10 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.102); catalogued as COSV100751472; called by muse, mutect2, varscan2
- SLC5A5 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV99714962; called by muse, mutect2, varscan2
- SLIT1 | c.1987C>A p.L663I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56586634, COSV99821083; called by muse, mutect2, varscan2
- SMAD5 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.197); catalogued as rs1473683347, COSV101548121; called by muse, mutect2, varscan2
- SMOX | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356192685, COSV53864572; called by muse, mutect2, varscan2
- SMU1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV68139475; called by muse, mutect2, varscan2
- SNRNP70 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs750368826, COSV99672249; called by muse, mutect2, varscan2
- SORBS2 | c.800G>A p.R267Q (on ENST00000284776 / NM_021069.5; = p.R360Q on NM_003603.6) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs769151662, COSV99510443; called by muse, mutect2, varscan2
- SOX7 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs142748053; called by muse, mutect2
- SPATA6 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV64057389; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPHKAP | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100763998; called by muse, mutect2, varscan2
- SREBF2 | c.2208C>T p.A736= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as rs201434289; called by muse, mutect2, varscan2
- STAG1 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99364061, COSV99365090; called by muse, mutect2, varscan2
- STAG2 | c.2707A>T p.T903S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99493048; called by muse, mutect2, varscan2
- STUB1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.438); catalogued as rs1427329505, COSV99555583; called by muse, mutect2, varscan2
- SULT1C2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369803535, COSV99265104; called by muse, mutect2, varscan2
- SULT1E1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99894880; called by muse, mutect2, varscan2
- SUV39H1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1457998837, COSV100551735; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs570102997; called by mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- TAF1 | c.2468G>A p.R823Q (on ENST00000373790 / NM_138923.4; = p.R844Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52115163; called by muse, mutect2, varscan2
- TAF1 | c.4091C>T p.T1364M (on ENST00000373790 / NM_138923.4; = p.T1385M on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1299710093, COSV99335355; called by muse, mutect2, varscan2
- TANC1 | c.5512A>G p.I1838V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs201176314; called by muse, mutect2, varscan2
- TANC2 | c.4864G>A p.V1622I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.796); catalogued as rs745873428, COSV67342522; called by muse, mutect2, varscan2
- TANC2 | c.5119G>T p.G1707C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs775502405, COSV101267350, COSV101267655; called by muse, mutect2, varscan2
- TBC1D32 | c.2666G>T p.R889M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99250000; called by muse, mutect2, varscan2
- TBRG1 | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400275642, COSV99422342; called by muse, mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- TCHH | c.4814G>A p.R1605H | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as rs763165126, COSV64275407; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 31/41 reads (76%) | catalogued as rs763321097; called by mutect2, varscan2
- TECR | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV99295058; called by muse, mutect2, varscan2
- TFRC | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100786439; called by muse, mutect2, varscan2
- TFRC | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100786440; called by muse, mutect2, varscan2
- TLE2 | c.234G>A p.A78= | Splice Region (SNP) | VAF 15/42 reads (36%) | catalogued as rs771383993, COSV99503971; called by muse, mutect2, varscan2
- TM9SF4 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1481100172, COSV54111580; called by muse, mutect2, varscan2
- TMED1 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as rs375902608, COSV99284085; called by muse, mutect2, varscan2
- TMEM45A | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs765084110, COSV100058282; called by muse, mutect2, varscan2
- TMEM94 | c.2059A>G p.S687G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV100050307; called by muse, varscan2
- TMLHE | c.636C>T p.I212= | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100544720; called by muse, mutect2, varscan2
- TNC | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs750966745, COSV60786750; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 29/33 reads (88%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNRC18 | c.4420G>T p.E1474* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV101269628; called by muse, mutect2, varscan2
- TNXB | c.9915dup p.I3306Hfs*30 (on ENST00000647633; = p.I3059Hfs*30 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/102 reads (27%) | catalogued as rs34629684; called by mutect2, pindel, varscan2
- TOGARAM1 | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779869465, COSV100753066; called by muse, mutect2, varscan2
- TRH | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100234783; called by muse, mutect2, varscan2
- TRIM3 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.277); catalogued as COSV100624346; called by muse, mutect2, varscan2
- TRIM35 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.442); catalogued as rs776766188, COSV59522632; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIO | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100710202, COSV60084352; called by muse, mutect2, varscan2
- TRMT13 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99790746; called by muse, mutect2, varscan2
- TRPV2 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs141744307; called by muse, mutect2, varscan2
- TRPV4 | c.1856T>G p.L619R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99924583; called by muse, mutect2, varscan2
- TRRAP | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147405090, COSV62839126, COSV62849075; called by muse, mutect2, varscan2
- TRRAP | c.5842A>G p.K1948E (on ENST00000359863 / NM_001244580.1; = p.K1930E on NM_003496.3) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100722313; called by muse, mutect2, varscan2
- TSC22D4 | c.587del p.P196Qfs*21 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs749248777; called by pindel, varscan2
- TSEN15 | c.185T>A p.V62E | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV100837335; called by muse, mutect2
- TSHZ1 | c.392G>T p.S131I (on ENST00000580243 / NM_001308210.2; = p.S86I on NM_005786.6) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100433539; called by muse, mutect2, varscan2
- TSHZ1 | c.1784C>T p.A595V (on ENST00000580243 / NM_001308210.2; = p.A550V on NM_005786.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100433541; called by muse, mutect2, varscan2
- TTLL9 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100206611; called by muse, mutect2, varscan2
- TUBA4A | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99944722; called by muse, mutect2, varscan2
- UBE2D4 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV99742461; called by muse, mutect2, varscan2
- UBE4A | c.2188G>A p.E730K (on ENST00000252108 / NM_001204077.2; = p.E737K on NM_004788.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782627132, COSV52803940, COSV99348244; called by muse, mutect2, varscan2
- UBN1 | c.2866A>G p.K956E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99277799; called by muse, mutect2, varscan2
- UGT1A5 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs754082390, COSV59400353; called by muse, mutect2, varscan2
- UHRF1 | c.262T>C p.S88P (on ENST00000612630 / NM_001290050.1; = p.S101P on NM_013282.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99503428; called by muse, mutect2, varscan2
- UNC5B | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100100613; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs767420916; called by mutect2, varscan2
- USF3 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.206); catalogued as COSV100325061; called by muse, mutect2, varscan2
- USP28 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs747036361, COSV50157894; called by muse, mutect2, varscan2
- USP36 | c.1958C>T p.T653M | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs143765903; called by muse, mutect2, varscan2
- USP43 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1208796939, COSV99556562; called by muse, mutect2, varscan2
- USP53 | c.2043G>A p.M681I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99917635; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 34/92 reads (37%) | catalogued as rs754083634; called by mutect2, varscan2
- VILL | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99378694; called by muse, mutect2, varscan2
- VIPR2 | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100056968; called by muse, mutect2, varscan2
- VPS13D | c.12753G>T p.Q4251H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99166094; called by muse, mutect2, varscan2
- VPS53 | c.2099A>G p.*700Wext*11 (on ENST00000571805 / NM_001366253.2; = p.*671Wext*11 on NM_018289.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV52129763; called by muse, mutect2
- WIZ | c.4633G>A p.V1545M (on ENST00000673675 / NM_001371589.1; = p.V450M on NM_021241.3) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.191); catalogued as rs372587052, COSV99652992; called by muse, mutect2, varscan2
- XKR6 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV58656363; called by muse, mutect2, varscan2
- ZAP70 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV53852372; called by muse, mutect2, varscan2
- ZBTB24 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV100018400; called by muse, mutect2, varscan2
- ZBTB33 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs376833183, COSV58532954; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | catalogued as rs751577786; called by mutect2, varscan2
- ZGPAT | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.091); catalogued as COSV100157524; called by muse, mutect2, varscan2
- ZIC1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1478245953; called by mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF274 | c.481C>T p.R161C (on ENST00000610905; = p.R56C on NM_016324.3) | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as rs775742516, COSV100464965; called by muse, mutect2, varscan2
- ZNF428 | c.250del p.R84Vfs*150 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs771244767, COSV56193931; called by mutect2, pindel, varscan2
- ZNF461 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs765875376, COSV64453133; called by muse, mutect2, varscan2
- ZNF629 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs897927925, COSV99354701; called by muse, mutect2, varscan2
- ZNF638 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781350176, COSV52491355; called by muse, mutect2, varscan2
- ZNF644 | c.871del p.R291Efs*7 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs749473342; called by mutect2, varscan2
- ZNF665 | c.11C>T p.A4V (on ENST00000600412; = p.A69V on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763838017, COSV67215483; called by muse, mutect2, varscan2
- ZNF669 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV100594247; called by muse, mutect2, varscan2
- ZNF862 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs751340307, COSV99783417; called by muse, mutect2, varscan2
- ZNRF4 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1341504479, COSV55772962; called by muse, mutect2, varscan2
- ZYG11B | c.1376A>T p.H459L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV99597145; called by muse, mutect2, varscan2
- AC098582.1 | c.528dup p.S177Lfs*42 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- ADAD2 | c.1029del p.K344Rfs*33 (on ENST00000315906 / NM_001145400.2; = p.K426Rfs*33 on NM_139174.4) | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.358_360del p.F120del | In Frame Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.3018_3020del p.F1007del | In Frame Del (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.2392_2393dup p.E799Lfs*9 (on ENST00000352432; = p.E765Lfs*9 on NM_001683.5) | Frame Shift Ins (INS) | VAF 52/128 reads (41%) | called by mutect2, varscan2
- BCAR1 | c.1976del p.G659Afs*43 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- BRMS1 | c.321del p.L108Cfs*22 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, varscan2
- BTF3L4 | c.135del p.K45Nfs*4 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- C4BPB | c.10del p.W4Gfs*53 | Frame Shift Del (DEL) | VAF 50/120 reads (42%) | called by mutect2, pindel, varscan2
- CAPN5 | c.2030del p.L677Pfs*13 (on ENST00000456580; = p.L637Pfs*13 on NM_004055.5) | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- CASKIN2 | c.1087del p.L363Cfs*71 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- CCDC186 | c.1844_1845del p.K615Sfs*4 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- CCDC8 | c.739del p.D247Ifs*62 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- CDHR3 | c.2108dup p.N703Kfs*76 | Frame Shift Ins (INS) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- CERS6 | c.540_542del p.Y182del | In Frame Del (DEL) | VAF 14/29 reads (48%) | called by pindel, varscan2
- CIC | c.3365_3366del p.V1122Gfs*28 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by pindel, varscan2
- CIC | c.4586del p.P1529Lfs*91 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- CIT | c.2750_2752del p.E917del | In Frame Del (DEL) | VAF 16/37 reads (43%) | called by mutect2, pindel, varscan2
- CRIM1 | c.261del p.L88Cfs*48 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- CRYGC | c.250del p.Q84Kfs*19 | Frame Shift Del (DEL) | VAF 35/104 reads (34%) | called by mutect2, pindel, varscan2
- DNAH3 | c.8485del p.V2829Yfs*9 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- DUSP14 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- EZH1 | c.1154_1156del p.E385del | In Frame Del (DEL) | VAF 16/38 reads (42%) | called by pindel, varscan2
- FAM168B | c.517del p.H173Tfs*63 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- FEZF1 | c.721del p.I241Sfs*35 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- FKBP14 | c.36_37del p.F13Rfs*11 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- FNDC11 | c.410del p.R137Lfs*38 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.503dup p.A169Gfs*14 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- GJB7 | c.306_307del p.R104Afs*27 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by pindel, varscan2
- GRK4 | c.1164dup p.Y389Ifs*17 (on ENST00000398052 / NM_182982.3; = p.Y357Ifs*17 on NM_005307.3) | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- HGF | c.60_62del p.L22del | In Frame Del (DEL) | VAF 7/22 reads (32%) | called by pindel, varscan2
- HOXA2 | c.989_990del p.T330Rfs*27 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2
- IGHV3-7 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGSF9B | c.439del p.Q147Sfs*13 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 39/63 reads (62%) | called by mutect2, pindel, varscan2
- IWS1 | c.2404del p.S802Afs*7 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | called by mutect2, varscan2
- JCAD | c.3088del p.A1030Qfs*35 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- JMJD1C | c.994del p.Y332Mfs*17 | Frame Shift Del (DEL) | VAF 47/114 reads (41%) | called by mutect2, pindel, varscan2
- KALRN | c.1825del p.E609Nfs*71 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- KMT2B | c.3302del p.P1101Lfs*81 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- KMT2C | c.8525dup p.N2842Kfs*2 | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | called by mutect2, varscan2
- KNTC1 | c.4938del p.K1646Nfs*2 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- KRT81 | c.93del p.Y32Tfs*71 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- LEO1 | c.1929_1931del p.E643del | In Frame Del (DEL) | VAF 14/45 reads (31%) | called by pindel, varscan2
- LIPT1 | c.79del p.T27Qfs*2 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- LRIG2 | c.780del p.F260Lfs*3 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- LTBP2 | c.5446del p.H1816Tfs*32 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- MMP20 | c.859del p.H287Ifs*19 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | called by mutect2, pindel, varscan2
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- NPVF | c.76del p.C26Vfs*5 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, varscan2
- OR51G1 | c.955del p.W319Gfs*? | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2807del p.K936Rfs*191 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- PCSK6 | c.748_750del p.C250del | In Frame Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1721_1722del p.R574Kfs*27 (on ENST00000521381 / NM_181523.3; = p.R304Kfs*27 on NM_181504.4) | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- PIK3R4 | c.915_917del p.E305del | In Frame Del (DEL) | VAF 11/25 reads (44%) | called by pindel, varscan2
- PITPNM3 | c.1137del p.P380Rfs*139 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | called by mutect2, pindel, varscan2
- PLEKHG4B | c.1695del p.A567Qfs*6 (on ENST00000283426; = p.A923Qfs*6 on NM_052909.5) | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- POTEM | c.1441T>C p.S481P | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); called by mutect2, varscan2
- PTPRM | c.2634del p.A879Pfs*14 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | called by mutect2, pindel, varscan2
- PUM2 | c.1054del p.V352Cfs*84 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- RANBP2 | c.4429dup p.S1477Ffs*17 | Frame Shift Ins (INS) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- RERE | c.248del p.K83Sfs*12 | Frame Shift Del (DEL) | VAF 42/119 reads (35%) | called by mutect2, varscan2
- RNF43 | c.931dup p.L311Pfs*132 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- SCAF11 | c.2009del p.N670Ifs*4 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- SCAF4 | c.618_619del p.Q206Hfs*14 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- SCLY | c.1049_1050del p.R350Nfs*5 (on ENST00000651534; = p.R342Nfs*5 on NM_016510.7) | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | called by pindel, varscan2
- SHPRH | c.1758del p.G587Efs*23 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- SLC35F6 | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- SND1 | c.2168del p.P723Lfs*2 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- SPCS3 | c.265_268del p.L89Qfs*11 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by pindel, varscan2
- STEAP2 | c.1400del p.K467Rfs*23 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- SYNGAP1 | c.2682dup p.S895Efs*43 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- TFCP2 | c.953del p.P318Lfs*41 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- TLR7 | c.1979del p.N660Ifs*3 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- TMEM165 | c.345del p.F115Lfs*2 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- TMUB2 | c.734del p.P245Qfs*70 (on ENST00000538716 / NM_001353177.2; = p.P225Qfs*70 on NM_024107.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- TNRC18 | c.7366del p.E2456Rfs*44 | Frame Shift Del (DEL) | VAF 44/124 reads (35%) | called by mutect2, pindel, varscan2
- TOR2A | c.503del p.P168Qfs*3 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- TRPV4 | c.235del p.V79Cfs*50 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- TRRAP | c.335del p.N112Mfs*5 | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | called by mutect2, pindel, varscan2
- UBASH3B | c.1019_1020del p.L340Hfs*13 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by pindel, varscan2
- UBQLN2 | c.1574del p.P525Lfs*71 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- UNC5CL | c.720dup p.R241Afs*64 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- USH1C | c.1433del p.K478Rfs*20 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- USP53 | c.951dup p.D318* | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- UTP23 | c.518_521del p.E173Vfs*11 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- ZNF358 | c.394del p.Q132Rfs*35 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- ZNF624 | c.2323_2324dup p.G776Lfs*21 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- ABCA2 | c.1471C>T p.L491= (on ENST00000614293; = p.L461= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs1398126072, COSV99687422; called by muse, mutect2, varscan2
- ABCE1 | c.1132C>T p.L378= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99668510; called by muse, mutect2, varscan2
- ABR | c.2394C>T p.T798= (on ENST00000302538 / NM_021962.5; = p.T761= on NM_001092.5) | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs765072551, COSV52146601; called by muse, mutect2, varscan2
- AC020907.6 | c.276C>T p.G92= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100032416; called by muse, mutect2, varscan2
- ACE | c.2298C>T p.L766= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs373339041; called by muse, mutect2, varscan2
- ADGRB2 | c.2385C>T p.G795= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV99926024; called by muse, mutect2, varscan2
- ADGRE5 | c.1773C>T p.F591= (on ENST00000242786 / NM_078481.4; = p.F498= on NM_001784.5) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99660239; called by muse, mutect2, varscan2
- ADRA2C | c.537G>A p.S179= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV57468411; called by muse, mutect2, varscan2
- AFG3L2 | c.952C>T p.L318= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs751688801, COSV99301752; called by muse, mutect2, varscan2
- AJAP1 | c.1080C>T p.C360= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1288652834, COSV65452214; called by muse, mutect2, varscan2
- ALPL | c.1275C>T p.G425= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs748883680, COSV100876206; called by muse, mutect2, varscan2
- ANKDD1A | c.514C>T p.L172= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs147441878; called by muse, mutect2, varscan2
- ANKK1 | c.1191G>A p.T397= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs890890791, COSV58273489; called by muse, mutect2, varscan2
- ANKRD22 | c.69G>A p.R23= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100905460; called by muse, mutect2, varscan2
- AP2A2 | c.1953C>A p.A651= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100172767; called by muse, mutect2, varscan2
- AP5Z1 | c.102G>A p.A34= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs764462865, COSV62244791; called by muse, mutect2, varscan2
- ARHGEF11 | c.3600C>T p.S1200= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs376078328; called by muse, mutect2, varscan2
- ASIC3 | c.831G>A p.P277= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs756905170, COSV52525158; called by muse, mutect2, varscan2
- ATP10A | c.3729C>T p.T1243= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs751467738, COSV63514140; called by muse, mutect2, varscan2
- ATRNL1 | c.3708C>A p.T1236= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100370147; called by muse, mutect2, varscan2
- BACE1 | c.618C>T p.H206= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100474967; called by muse, mutect2, varscan2
- BIRC6 | c.13707G>A p.A4569= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs144705632, COSV70206360; called by muse, mutect2
- BRCA2 | c.2214T>C p.C738= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV101204119; called by muse, mutect2, varscan2
- BRF1 | c.849C>T p.I283= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs587663572, COSV100527152; called by muse, mutect2, varscan2
- BROX | c.948G>A p.V316= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100572155; called by muse, mutect2, varscan2
- CADPS | c.3219C>A p.A1073= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99337300; called by muse, mutect2
- CAPN15 | c.1551A>G p.R517= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99562350; called by muse, mutect2, varscan2
- CBLL1 | c.1218T>C p.P406= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV56029332; called by muse, mutect2, varscan2
- CCDC22 | c.978G>A p.T326= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs368244237, COSV100873125, COSV100873270, COSV66051828; called by muse, mutect2, varscan2
- CDH24 | c.1845C>T p.C615= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1162307153, COSV57460366; called by muse, mutect2, varscan2
- CENPM | c.540G>A p.L180= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV99317824; called by muse, mutect2, varscan2
- CEP89 | c.1704C>T p.A568= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs761903654, COSV99993323; called by muse, mutect2, varscan2
- CFAP54 | c.7161C>T p.C2387= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100732856, COSV100733081; called by muse, mutect2, varscan2
- CHD3 | c.51G>A p.Q17= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV100391037; called by muse, mutect2, varscan2
- CLCN5 | c.2118G>A p.L706= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100260011; called by muse, mutect2, varscan2
- CLSPN | c.2010A>G p.E670= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99230691; called by muse, mutect2, varscan2
- CNTROB | c.1392G>A p.A464= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs772530631, COSV100972654; called by muse, mutect2, varscan2
- CREBBP | c.6549G>A p.A2183= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1348561145, COSV99269450; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTC1 | c.2157C>A p.P719= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100236333; called by muse, mutect2, varscan2
- DACH2 | c.42C>T p.S14= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100912996; called by muse, mutect2, varscan2
- DDX60L | c.4608G>A p.E1536= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs964262767, COSV99487386; called by muse, mutect2, varscan2
- DISP1 | c.2376C>T p.G792= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs753722465, COSV52654875; called by muse, mutect2, varscan2
- DLGAP1 | c.2307G>A p.P769= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs911696769, COSV100229508; called by muse, mutect2, varscan2
- DNAH2 | c.7338C>T p.S2446= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs532707394, COSV66720238; called by muse, mutect2, varscan2
- DNM2 | c.2415G>A p.S805= (on ENST00000355667 / NM_001005360.3; = p.S801= on NM_004945.3) | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as rs920872155, COSV99284084; called by muse, mutect2, varscan2
- DOCK4 | c.2433C>T p.C811= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1379855424, COSV101447828; called by muse, mutect2, varscan2
- DPP6 | c.1983C>T p.D661= (on ENST00000377770 / NM_001364500.2; = p.D599= on NM_001936.5) | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as rs372493523; called by muse, mutect2, varscan2
- DRGX | c.495C>A p.A165= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100938322; called by muse, mutect2, varscan2
- ECRG4 | c.369T>C p.Y123= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs532790057, COSV99430296; called by muse, mutect2, varscan2
- EDN2 | c.177C>T p.C59= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs759074879, COSV101006332; called by muse, mutect2, varscan2
- EGFL8 | c.402C>T p.P134= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs751693749, COSV100246888; called by muse, mutect2, varscan2
- EZHIP | c.675C>T p.R225= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100539618; called by muse, mutect2, varscan2
- FAM126B | c.1371T>C p.F457= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99627652; called by muse, mutect2, varscan2
- FCGBP | c.12309G>A p.T4103= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs769741833; called by muse, mutect2, varscan2
- FKBP5 | c.489C>T p.N163= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs771671530, COSV100616135; called by muse, mutect2, varscan2
- GJA3 | c.726C>A p.A242= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99576317; called by muse, mutect2
- GRM8 | c.123G>A p.R41= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1230957713, COSV100282013; called by muse, mutect2, varscan2
- GSX1 | c.642C>T p.G214= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1302258904, COSV57232477; called by muse, mutect2, varscan2
- HCFC1 | c.5088G>A p.Q1696= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100128788; called by muse, mutect2
- HOXD12 | c.630G>A p.T210= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV101184123, COSV66832350; called by muse, mutect2, varscan2
- HPX | c.31C>T p.L11= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1208718132, COSV56419460; called by muse, mutect2, varscan2
- HRNR | c.6246C>T p.G2082= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100912781, COSV100913299; called by muse, mutect2, varscan2
- HYDIN | c.417G>A p.S139= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs529209604, COSV55484586; called by muse, mutect2, varscan2
- IFT122 | c.2979C>A p.I993= (on ENST00000348417 / NM_052989.3; = p.I934= on NM_018262.4) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99959111; called by muse, mutect2, varscan2
- IGSF10 | c.6558C>T p.S2186= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs1441136151; called by muse, mutect2
- IL17RA | c.1554C>T p.G518= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100083035; called by muse, mutect2, varscan2
- IL5RA | c.636G>T p.A212= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99842854; called by muse, mutect2, varscan2
- IRX1 | c.1410G>A p.T470= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100116407; called by muse, mutect2, varscan2
- ITGB8 | c.1449T>C p.D483= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs61753451, COSV99751180; called by muse, mutect2, varscan2
- ITIH6 | c.175C>T p.L59= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV99513143; called by muse, mutect2, varscan2
- KCND3 | c.618G>A p.P206= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs200611538, COSV100137130; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNF1 | c.423C>T p.I141= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as rs763139502, COSV99705666; called by muse, mutect2, varscan2
- KCNJ4 | c.327G>T p.V109= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100341116; called by muse, mutect2
- KIAA1217 | c.4680C>T p.D1560= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs760647439, COSV100286435; called by muse, mutect2, varscan2
- KIAA1755 | c.519T>C p.I173= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99641836; called by muse, mutect2, varscan2
- KIF4A | c.3201C>T p.D1067= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs767770689, COSV100979474; called by muse, mutect2, varscan2
- KLHL21 | c.1461G>A p.P487= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs1053737566, COSV100887202, COSV100887217; called by muse, mutect2, varscan2
- KLK10 | c.162C>T p.R54= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as COSV100011035; called by muse, mutect2, varscan2
- KMT5C | c.750G>A p.A250= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs377152615; called by muse, mutect2, varscan2
- KPRP | c.576C>T p.G192= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs527838600, COSV100908686; called by muse, mutect2, varscan2
- KSR2 | c.783G>A p.P261= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs778155102, COSV60387410; called by muse, mutect2, varscan2
- LRIG2 | c.2631T>C p.H877= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100743245; called by muse, mutect2, varscan2
- LRRIQ4 | c.1248C>A p.S416= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100540182, COSV61619099; called by muse, mutect2, varscan2
- MAFG | c.165C>A p.R55= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100155473; called by muse, mutect2
- MAGEB6 | c.537C>T p.S179= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs148547775, COSV66873211; called by muse, mutect2, varscan2
- MAP2K7 | c.655C>T p.L219= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV101209022; called by muse, mutect2, varscan2
- MAP3K15 | c.3342C>T p.F1114= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs1330351180, COSV58837696; called by muse, varscan2
- MFSD10 | c.127C>T p.L43= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99296311; called by muse, mutect2, varscan2
- MGMT | c.207G>A p.T69= (on ENST00000306010; = p.T38= on NM_002412.5) | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs751269604, COSV100022835, COSV60032052; called by muse, mutect2, varscan2
- MS4A14 | c.18G>A p.Q6= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs765668736, COSV100279463; called by muse, mutect2, varscan2
- MTHFR | c.1491C>T p.I497= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs143480693; called by muse, varscan2
- MUC16 | c.34761G>A p.T11587= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs1187325557, COSV101199348, COSV67468848; called by muse, mutect2, varscan2
- MXRA5 | c.3177T>C p.G1059= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99476465; called by muse, mutect2, varscan2
- MYH7 | c.1332T>C p.N444= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs397516099, COSV100805954; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCOA6 | c.6042C>G p.G2014= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100749951; called by muse, mutect2, varscan2
- NEK9 | c.2274C>T p.G758= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs376937236; called by muse, mutect2, varscan2
- NFATC2 | c.351G>A p.P117= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1232977168, COSV101043918; called by muse, mutect2, varscan2
- NKX6-3 | c.684C>T p.D228= (on ENST00000518699 / NM_001364841.2; = p.D98= on NM_152568.3) | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV101570817; called by muse, mutect2, varscan2
- NLGN2 | c.1728G>A p.K576= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs749360027, COSV100080950; called by muse, mutect2, varscan2
- NPAT | c.3672T>A p.G1224= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV99585924; called by muse, mutect2, varscan2
- NPLOC4 | c.135G>A p.S45= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV58619594; called by muse, mutect2, varscan2
- NVL | c.2247G>A p.P749= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as rs769904366, COSV99894051; called by muse, mutect2, varscan2
- NVL | c.1293C>T p.C431= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99894053; called by muse, mutect2, varscan2
- OR2M2 | c.717G>A p.T239= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs375862698, COSV100677199, COSV62898574; called by muse, mutect2
- OR2M5 | c.69C>A p.T23= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100822793; called by muse, mutect2, varscan2
- OR51A4 | c.819T>C p.I273= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV100985232; called by muse, mutect2, varscan2
- OR52N4 | c.64C>T p.L22= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100421661; called by muse, mutect2, varscan2
- PARP14 | c.4293G>A p.V1431= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV71734793; called by muse, mutect2, varscan2
- PCDH11X | c.3504C>A p.A1168= | Silent (SNP) | VAF 3/53 reads (6%) | catalogued as COSV100010824; called by muse, mutect2
- PCDHA8 | c.1101T>C p.T367= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV100970630; called by muse, mutect2, varscan2
- PCDHB7 | c.1830G>A p.T610= | Silent (SNP) | VAF 42/380 reads (11%) | catalogued as rs554758462, COSV99176764; called by muse, mutect2, varscan2
- PDE8B | c.1053C>T p.S351= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs753464504, COSV99366571; called by muse, varscan2
- PELO | c.306C>A p.I102= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99251083; called by muse, mutect2, varscan2
- PFKP | c.2178C>T p.N726= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs374581817; called by muse, mutect2, varscan2
- PHACTR4 | c.870G>A p.P290= (on ENST00000373839 / NM_001350159.2; = p.P300= on NM_023923.4) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs201982408; called by muse, mutect2, varscan2
- PHC1 | c.1293A>G p.Q431= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs753984691, COSV101418568; called by muse, mutect2, varscan2
- PHF19 | c.525G>A p.V175= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs758812919, COSV100384302; called by muse, mutect2, varscan2
- PIGV | c.234C>T p.G78= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as COSV99314874; called by muse, mutect2, varscan2
- PLA2G4F | c.217C>T p.L73= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV99300521; called by muse, mutect2, varscan2
- PLEKHG4 | c.2811T>C p.T937= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs775172213, COSV100430832; called by muse, mutect2, varscan2
- POLR2A | c.318T>A p.V106= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100495651; called by muse, mutect2, varscan2
- PPP2R5B | c.153C>T p.R51= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99376038; called by muse, mutect2, varscan2
- PTDSS2 | c.201C>T p.T67= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs143983958, COSV100339101; called by muse, mutect2, varscan2
- PXDN | c.1203C>T p.N401= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1381055153, COSV53238596; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAPGEF2 | c.3981G>A p.A1327= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs754475763, COSV52428479; called by muse, mutect2, varscan2
- RAPH1 | c.3309C>T p.V1103= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1338464109, COSV99863629; called by muse, mutect2, varscan2
- SARDH | c.2718C>A p.P906= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV100898378; called by muse, mutect2, varscan2
- SBF1 | c.411G>A p.S137= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs769350649, COSV62370334; called by muse, mutect2, varscan2
- SEL1L3 | c.2209C>T p.L737= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99339962; called by muse, mutect2, varscan2
- SEMA3G | c.1938C>T p.S646= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV51599205; called by muse, mutect2, varscan2
- SEMA4C | c.387C>T p.G129= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100560860; called by muse, mutect2, varscan2
- SERGEF | c.234T>C p.D78= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99787109; called by muse, mutect2
- SF1 | c.1011C>T p.T337= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV99918195; called by muse, mutect2, varscan2
- SGSM2 | c.2562G>A p.Q854= (on ENST00000426855 / NM_001098509.2; = p.Q899= on NM_014853.3) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99280008; called by muse, mutect2, varscan2
- SIGIRR | c.1026G>A p.R342= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs976075687, COSV100229925; called by muse, mutect2, varscan2
- SIN3A | c.867G>A p.S289= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as rs769881227, COSV64583652; called by muse, mutect2, varscan2
- SLC18A3 | c.942G>A p.T314= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs374372621, COSV60331755; called by muse, mutect2, varscan2
- SLC25A12 | c.1677T>G p.G559= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99784671, COSV99784869; called by muse, mutect2, varscan2
- SLC4A11 | c.2178G>A p.P726= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs200459526, COSV101195931; called by muse, mutect2, varscan2
- SLC52A2 | c.1065G>A p.A355= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs200618841, COSV57352838; called by muse, mutect2, varscan2
- SLC5A9 | c.594C>T p.A198= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs754943451, COSV99361558; called by muse, mutect2, varscan2
- SLC9A6 | c.1587A>G p.A529= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100857884; called by muse, mutect2, varscan2
- SLITRK3 | c.1092G>A p.Q364= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV99578943; called by muse, mutect2, varscan2
- SNX7 | c.672C>T p.G224= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100068834; called by muse, mutect2, varscan2
- SPTBN2 | c.1464T>C p.A488= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100018943; called by muse, varscan2
- SRPX2 | c.729C>T p.A243= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1280564665, COSV100884013; called by muse, mutect2, varscan2
- ST8SIA4 | c.936C>T p.V312= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99185196; called by muse, mutect2, varscan2
- STK35 | c.1170G>A p.G390= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99852712; called by muse, mutect2, varscan2
- SV2B | c.303G>A p.E101= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV100370568; called by muse, mutect2, varscan2
44 further variants in this file (0 protein-altering or splice-affecting, 21 silent, 23 other) are not listed here.
